Somatic mutation profile of tumor specimen TARGET-20-PASBII-09A (aliquot TARGET-20-PASBII-09A-01D) from TARGET case TARGET-20-PASBII, project TARGET-AML (Acute Myeloid Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute myeloid leukemia, NOS; Tissue or organ of origin: Bone marrow; Age at diagnosis: 17.5 years (6,384 days).
Specimen TARGET-20-PASBII-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9987586d-94b9-48cf-8f53-c37b39da09bf.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-20-PASBII-14A (Bone Marrow Normal), aliquot TARGET-20-PASBII-14A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/8129cb40-72c0-48ee-a88f-99b140c48f8b

The open-access MAF lists 2 somatic variants for this specimen: 2 protein-altering or splice-affecting.
By variant classification: Missense Mutation 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- DHX15 | c.664C>G p.R222G | Missense Mutation (SNP) | VAF 7/153 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61028061, COSV61028114, COSV61028271; called by muse, mutect2
- FOXP2 | c.1326C>A p.S442R | Missense Mutation (SNP) | VAF 13/85 reads (15%) | SIFT tolerated (0.09); PolyPhen benign (0.052); catalogued as COSV63484185; called by muse, mutect2, varscan2
